Somatic mutation profile of tumor specimen 0DRIW9 from CCDI case PBCGMK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,664 days).
Specimen 0DRIW9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a337a7e3-d395-434d-9ea7-bd71b960eec3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRIWG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55edf3d0-7b90-4da1-bc96-274c6c39639d

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/846 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BEND2 | c.2306A>T p.E769V | Missense Mutation (SNP) | VAF 70/818 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- PAXIP1 | c.478A>T p.I160F | Missense Mutation (SNP) | VAF 72/1404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 16/432 reads (4%) | called by muse, mutect2
- RBM11 | c.633C>T p.S211= | Silent (SNP) | VAF 84/1346 reads (6%) | catalogued as rs370200402; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/220 reads (6%) | called by muse, mutect2
- TNPO1 | c.-8C>T | 5'UTR (SNP) | VAF 67/575 reads (12%) | catalogued as rs375884663; called by muse, mutect2, varscan2
- UBN2 | c.-15G>C | 5'UTR (SNP) | VAF 10/157 reads (6%) | catalogued as rs1361679026; called by muse, mutect2
